Somatic mutation profile of tumor specimen TCGA-D5-6927-01A (aliquot TCGA-D5-6927-01A-21D-1924-10) from TCGA case TCGA-D5-6927, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 34.9 years (12,737 days).
Specimen TCGA-D5-6927-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 925d090f-7835-4078-ab2e-b6ae72a7f560.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6927-10A (Blood Derived Normal), aliquot TCGA-D5-6927-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51ce487e-22eb-4d77-a20d-356ebd200f0f

The open-access MAF lists 823 somatic variants for this specimen: 632 protein-altering or splice-affecting, 175 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 418, Silent 175, Frame Shift Del 126, Frame Shift Ins 36, Nonsense Mutation 22, Splice Site 16, Intron 9, Splice Region 8, In Frame Del 5, RNA 3, 3'UTR 2, 5'UTR 2.

Variants (750 of 823; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG11 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886039306, COSV73000694; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- B4GALNT1 | c.263del p.G88Afs*24 | Frame Shift Del (DEL) | VAF 11/22 reads (50%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BMPR2 | c.1259G>A p.C420Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1085307325, CM041257, COSV101001450; ClinVar: pathogenic; called by muse, mutect2
- COL4A3 | c.1918G>A p.G640R | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as rs200672668, CM014042; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 70/120 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- DMD | c.3940C>T p.R1314* | Nonsense Mutation (SNP) | VAF 50/92 reads (54%) | catalogued as rs5030730, CM100263, CS002446, COSV63740877; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EYA1 | c.229C>T p.R77* | Nonsense Mutation (SNP) | VAF 9/61 reads (15%) | catalogued as rs200164773, COSV58164819; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 40/143 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GLDN | c.1240C>T p.R414* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as rs539703340, COSV59090127; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HSPG2 | c.1219dup p.Q407Pfs*62 | Frame Shift Ins (INS) | VAF 10/46 reads (22%) | catalogued as rs763945561; ClinVar: likely pathogenic; called by mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 41/143 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NCSTN | c.17del p.G6Vfs*22 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | catalogued as rs1266104510; ClinVar: pathogenic; called by mutect2, pindel
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 33/130 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 28/106 reads (26%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 71/297 reads (24%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SACS | c.6172dup p.S2058Ffs*2 | Frame Shift Ins (INS) | VAF 15/54 reads (28%) | catalogued as rs1214399996; ClinVar: pathogenic; called by mutect2, varscan2
- A2M | c.2159T>C p.L720P | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.141); catalogued as COSV100588631; called by muse, mutect2
- A2ML1 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372782124; called by muse, mutect2, varscan2
- ABCA2 | c.5263C>T p.R1755C (on ENST00000614293; = p.R1725C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs1362222609, COSV55802414; called by muse, mutect2, varscan2
- ABCA3 | c.2175G>T p.E725D | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57054888; called by muse, mutect2, varscan2
- ABCB1 | c.2455G>A p.A819T | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200754866, COSV55952144; called by muse, mutect2, varscan2
- ABCB6 | c.1386G>A p.T462= | Splice Region (SNP) | VAF 33/135 reads (24%) | catalogued as rs778740925, COSV54694246; called by muse, mutect2, varscan2
- AC127029.3 | c.895G>A p.V299M | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.007); catalogued as rs916741851, COSV60111124; called by muse, mutect2, varscan2
- ACE | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV52008050; called by muse, mutect2, varscan2
- ACKR3 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as rs764138712, COSV56021529; called by muse, mutect2, varscan2
- ACSL1 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1275283484, COSV55663399, COSV99860690; called by muse, mutect2, varscan2
- ACSL1 | c.44T>C p.L15P | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs1350238373, COSV55663407; called by muse, mutect2, varscan2
- ACSM4 | c.1369G>T p.G457* | Nonsense Mutation (SNP) | VAF 43/242 reads (18%) | catalogued as COSV68068025; called by muse, mutect2, varscan2
- ACTG1 | c.704_706del p.S235del | In Frame Del (DEL) | VAF 11/70 reads (16%) | catalogued as rs782541695, COSV59510785; called by mutect2, pindel, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 52/96 reads (54%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM29 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 66/241 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs746641739, COSV63663321; called by muse, mutect2, varscan2
- ADAMTS14 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.071); catalogued as COSV64602842; called by muse, mutect2, varscan2
- ADAMTS17 | c.3223C>A p.R1075S | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51483124; called by muse, mutect2, varscan2
- ADAMTS3 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as rs1326633039, COSV54393820; called by muse, mutect2, varscan2
- ADAMTS8 | c.2545G>A p.G849R | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs768909867, COSV57294116; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4123del p.Q1375Kfs*24 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | catalogued as COSV65879385; called by mutect2, varscan2
- ADAMTSL3 | c.1705A>G p.I569V | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV99718524; called by muse, mutect2, varscan2
- ADGRE1 | c.880T>C p.C294R | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99165230; called by muse, mutect2, varscan2
- ADGRG1 | c.1033C>T p.Q345* | Nonsense Mutation (SNP) | VAF 20/75 reads (27%) | catalogued as COSV65635764; called by muse, mutect2, varscan2
- ADGRG2 | c.366del p.F122Lfs*21 (on ENST00000379869 / NM_001079858.3; = p.F119Lfs*21 on NM_005756.4) | Frame Shift Del (DEL) | VAF 45/120 reads (38%) | catalogued as COSV61341022; called by mutect2, pindel, varscan2
- ADGRG4 | c.7457G>A p.G2486D | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99795313; called by muse, mutect2
- ADGRV1 | c.13983del p.L4664Cfs*23 | Frame Shift Del (DEL) | VAF 47/199 reads (24%) | catalogued as rs751429551; called by mutect2, pindel, varscan2
- ADM2 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as rs916080630, COSV53313348; called by muse, mutect2
- AGA | c.416T>C p.M139T | Missense Mutation (SNP) | VAF 49/216 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV52806569; called by muse, mutect2, varscan2
- AGGF1 | c.611A>C p.Q204P | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100461784; called by muse, mutect2
- AKAP9 | c.11307dup p.Q3770Afs*52 (on ENST00000359028; = p.Q3746Afs*52 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | catalogued as rs747796926; called by mutect2, varscan2
- ALDH7A1 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.04); catalogued as rs765795361, COSV100778263; called by mutect2, varscan2
- ALG13 | c.2143T>C p.Y715H | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV52640081; called by muse, mutect2, varscan2
- ALOX5 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV65552818; called by muse, mutect2, varscan2
- ALS2 | c.3395G>A p.R1132H | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753713733, COSV51888123; called by muse, mutect2, varscan2
- ALX4 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.273); catalogued as rs748769921, COSV61326921; called by muse, mutect2, varscan2
- ANKFY1 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1198079816, COSV58915943; called by muse, mutect2, varscan2
- ANKIB1 | c.437del p.N146Tfs*12 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs201434379; called by mutect2, varscan2
- ANKRA2 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as rs150789725; called by muse, mutect2, varscan2
- ANKRD13A | c.735-1G>T p.X245_splice | Splice Site (SNP) | VAF 43/211 reads (20%) | catalogued as COSV55676758; called by muse, mutect2, varscan2
- ANKRD28 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs779113898, COSV67516906; called by muse, mutect2, varscan2
- ANO5 | c.953C>A p.A318D | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61086041; called by muse, mutect2, varscan2
- AOC2 | c.1202A>G p.Q401R | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.425); catalogued as COSV53199485, COSV99513704; called by muse, mutect2, varscan2
- APBA1 | c.2009T>C p.V670A | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.852); catalogued as COSV99595958; called by muse, mutect2, varscan2
- APBB3 | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100021283; called by muse, mutect2
- APOB | c.2436+2T>C p.X812_splice | Splice Site (SNP) | VAF 25/70 reads (36%) | catalogued as COSV51938803; called by muse, mutect2, varscan2
- ARHGAP39 | c.1095del p.S366Rfs*18 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs751388541; called by mutect2, varscan2
- ARPP21 | c.1007A>G p.D336G | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV51799713; called by muse, mutect2, varscan2
- ARRDC1 | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as rs376105916; called by muse, mutect2, varscan2
- ASB4 | c.287A>G p.D96G | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV57508174; called by muse, mutect2, varscan2
- ASIC1 | c.998A>G p.D333G | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.063); catalogued as COSV57318368; called by muse, mutect2, varscan2
- ASTN1 | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56065747, COSV99029663, COSV99920176; called by muse, mutect2, varscan2
- ATF5 | c.73G>A p.V25I | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.042); catalogued as rs745985003, COSV61312360; called by muse, mutect2, varscan2
- ATG10 | c.483del p.F161Lfs*12 | Frame Shift Del (DEL) | VAF 34/148 reads (23%) | catalogued as rs1186430519; called by mutect2, pindel, varscan2
- ATL1 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as rs754423972, COSV63296622; called by muse, mutect2, varscan2
- ATP11A | c.2198C>T p.T733M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as rs770429974, COSV52109832; called by muse, mutect2, varscan2
- ATP1A2 | c.2000T>C p.L667P | Missense Mutation (SNP) | VAF 13/209 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100767802; called by muse, mutect2
- ATP5F1B | c.968G>A p.G323D | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV56261180; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV57749811; called by muse, mutect2, varscan2
- BAIAP2L1 | c.364T>C p.Y122H | Missense Mutation (SNP) | VAF 71/290 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV50056728; called by muse, mutect2, varscan2
- BATF2 | c.233A>G p.H78R | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.133); catalogued as COSV57250105; called by muse, mutect2, varscan2
- BBS2 | c.806T>C p.V269A | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV99802354; called by muse, mutect2, varscan2
- BCHE | c.1135C>T p.Q379* | Nonsense Mutation (SNP) | VAF 37/136 reads (27%) | catalogued as COSV52257717; called by muse, mutect2, varscan2
- BCL2L2 | c.505T>C p.S169P | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as COSV51636123; called by muse, mutect2, varscan2
- BCL9L | c.3380dup p.P1128Tfs*42 | Frame Shift Ins (INS) | VAF 31/146 reads (21%) | catalogued as rs751794665; called by mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 30/118 reads (25%) | catalogued as rs755506199; called by mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 28/114 reads (25%) | catalogued as rs772920507, COSV65808737; called by mutect2, varscan2
- BRAT1 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs769006340, COSV61395747; called by muse, mutect2, varscan2
- BRINP2 | c.661del p.A221Pfs*53 | Frame Shift Del (DEL) | VAF 32/104 reads (31%) | catalogued as COSV64180297; called by mutect2, pindel, varscan2
- BRWD1 | c.6805dup p.H2269Pfs*9 | Frame Shift Ins (INS) | VAF 70/287 reads (24%) | catalogued as rs566481004; called by mutect2, pindel, varscan2
- BSCL2 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as COSV54016075; called by muse, mutect2, varscan2
- BSN | c.3139C>T p.R1047W | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759186312, COSV56519997; called by muse, mutect2, varscan2
- C10orf120 | c.253-1G>T p.X85_splice | Splice Site (SNP) | VAF 40/141 reads (28%) | catalogued as COSV61492127, COSV61492813; called by muse, mutect2, varscan2
- C11orf68 | c.350A>G p.Q117R (on ENST00000530188; = p.Q158R on NM_031450.4) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV100437087; called by muse, mutect2, varscan2
- C1QTNF12 | c.595G>C p.A199P | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57802774; called by muse, mutect2, varscan2
- C1orf116 | c.1433A>G p.N478S | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as COSV100847925; called by muse, mutect2
- C1orf127 | c.2353C>T p.R785W | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.736); catalogued as rs370862831; called by muse, mutect2, varscan2
- C2orf78 | c.1070del p.N357Mfs*17 | Frame Shift Del (DEL) | VAF 20/89 reads (22%) | catalogued as rs1242308663; called by mutect2, pindel, varscan2
- C3orf18 | c.216A>G p.I72M | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs775853756, COSV51750703; called by muse, mutect2, varscan2
- C5 | c.2435C>T p.A812V | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV56328456; called by muse, mutect2, varscan2
- C7orf31 | c.134G>T p.R45M | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52218176; called by muse, mutect2, varscan2
- CACNA1B | c.5191C>T p.R1731W | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53112622, COSV53129874; called by muse, mutect2
- CACNA1E | c.3438C>A p.C1146* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | catalogued as COSV62399772; called by muse, mutect2, varscan2
- CACNG6 | c.626del p.P209Rfs*21 (on ENST00000252729 / NM_145814.1; = p.P138Rfs*21 on NM_031897.2) | Frame Shift Del (DEL) | VAF 11/68 reads (16%) | catalogued as rs745648688, COSV53168096; called by mutect2, pindel, varscan2
- CAMSAP2 | c.2894G>A p.R965H (on ENST00000236925 / NM_001297707.2; = p.R954H on NM_203459.3) | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.056); catalogued as rs144674686; called by muse, mutect2, varscan2
- CAMSAP2 | c.3715C>T p.R1239W (on ENST00000236925 / NM_001297707.2; = p.R1228W on NM_203459.3) | Missense Mutation (SNP) | VAF 82/354 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199622691, COSV52667532; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 34/138 reads (25%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CARMIL3 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV57726794; called by muse, mutect2, varscan2
- CASP2 | c.1129A>G p.M377V | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV60082493; called by muse, mutect2, varscan2
- CASP5 | c.143T>C p.L48P | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.29); catalogued as COSV52829126; called by muse, varscan2
- CCDC127 | c.122-2A>G p.X41_splice | Splice Site (SNP) | VAF 40/146 reads (27%) | catalogued as rs374774826; called by muse, mutect2
- CCDC51 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.958); catalogued as COSV56490682; called by muse, mutect2, varscan2
- CCDC71 | c.1292T>C p.V431A | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100422349; called by muse, mutect2
- CCDC71 | c.371G>A p.R124K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.142); catalogued as COSV58910305; called by muse, mutect2, varscan2
- CCDC80 | c.919G>T p.G307C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV52817420; called by muse, mutect2, varscan2
- CCNA1 | c.1116T>A p.S372R | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99714537; called by muse, mutect2
- CCNE1 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52904737; called by muse, mutect2, varscan2
- CCT8L2 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs576628432, COSV63462794, COSV63464141; called by muse, mutect2, varscan2
- CD22 | c.2375A>G p.D792G | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.076); catalogued as rs995445726, COSV50054913; called by muse, mutect2, varscan2
- CD2BP2 | c.159G>T p.E53D | Missense Mutation (SNP) | VAF 68/237 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as rs751813994, COSV59769105, COSV59769147; called by muse, mutect2, varscan2
- CDHR2 | c.2332G>A p.V778M | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99991499; called by muse, mutect2
- CDHR3 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.145); catalogued as rs1461518004, COSV58418102; called by muse, mutect2, varscan2
- CDK14 | c.1016A>G p.Q339R (on ENST00000380050 / NM_001287135.2; = p.Q321R on NM_012395.3) | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.954); catalogued as rs1209507684, COSV99724981; called by muse, mutect2, varscan2
- CDNF | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.412); catalogued as rs369901027, COSV65805724; called by muse, mutect2, varscan2
- CDX2 | c.916del p.V306Cfs*2 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs773511514; called by mutect2, pindel, varscan2
- CELSR3 | c.3899C>T p.A1300V | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV50880625; called by muse, mutect2, varscan2
- CERT1 | c.1402-3del | Splice Region (DEL) | VAF 29/128 reads (23%) | catalogued as rs768479535; called by mutect2, pindel, varscan2
- CHSY3 | c.1390A>T p.I464L | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV59278807; called by muse, mutect2, varscan2
- CKAP5 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV56368881; called by muse, mutect2, varscan2
- CLCC1 | c.1189G>A p.D397N (on ENST00000356970 / NM_001377464.1; = p.D347N on NM_015127.5) | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as rs751983843, COSV100206431; called by muse, varscan2
- CLEC11A | c.322G>T p.V108F | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV51573868, COSV51574234; called by muse, mutect2, varscan2
- CLEC14A | c.1220T>C p.V407A | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs910482314, COSV60562806; called by muse, mutect2
- CLEC3A | c.167A>G p.Q56R (on ENST00000651443; = p.Q47R on NM_005752.6) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.543); catalogued as COSV100222207; called by muse, mutect2, varscan2
- CLUH | c.3151G>A p.E1051K (on ENST00000435359; = p.E1090K on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101425726; called by muse, mutect2
- CNOT1 | c.6788G>A p.R2263H | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54699718; called by muse, mutect2, varscan2
- CNOT1 | c.5198G>A p.R1733H | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs185344213, COSV55312634; called by muse, mutect2, varscan2
- CNTN2 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs371816961, COSV59350646; called by muse, mutect2, varscan2
- CNTN2 | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs139732381; called by muse, mutect2, varscan2
- CNTNAP2 | c.2201G>A p.R734H | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1060503570, COSV62193955; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COBL | c.3206A>C p.K1069T | Missense Mutation (SNP) | VAF 51/207 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV54348195; called by muse, mutect2, varscan2
- COG2 | c.1673G>T p.S558I | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV64187230; called by muse, mutect2, varscan2
- COG5 | c.1543A>G p.I515V | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV51753578; called by muse, varscan2
- COL11A1 | c.3680G>T p.R1227I | Missense Mutation (SNP) | VAF 99/420 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62185777, COSV62189510; called by muse, mutect2, varscan2
- COL22A1 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as rs143614201, COSV100278770; called by muse, mutect2, varscan2
- COPS2 | c.512T>A p.I171N | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV54645624; called by muse, mutect2, varscan2
- CPT1C | c.784G>A p.V262I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.042); catalogued as COSV54919844; called by muse, mutect2, varscan2
- CSNK2A2 | c.296T>A p.I99N | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV52642396; called by muse, mutect2, varscan2
- CTCF | c.1555G>A p.G519R | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs911362614, COSV50472696; called by muse, mutect2, varscan2
- CXCL9 | c.276+1G>T p.X92_splice | Splice Site (SNP) | VAF 15/141 reads (11%) | catalogued as rs747595704, COSV53579061; called by muse, mutect2, varscan2
- CYFIP1 | c.767C>T p.T256M | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.674); catalogued as rs750340297; called by muse, mutect2, varscan2
- CYFIP2 | c.877A>G p.S293G | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as COSV59040962; called by muse, mutect2, varscan2
- CYFIP2 | c.1570C>T p.R524* | Nonsense Mutation (SNP) | VAF 21/81 reads (26%) | catalogued as COSV59033939; called by muse, mutect2, varscan2
- CYP24A1 | c.538A>G p.N180D | Missense Mutation (SNP) | VAF 67/210 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.623); catalogued as COSV53774946; called by muse, mutect2, varscan2
- CYP27C1 | c.1086del p.I364Sfs*14 | Frame Shift Del (DEL) | VAF 32/127 reads (25%) | catalogued as rs767024106; called by mutect2, pindel, varscan2
- DAB2 | c.1760_1762del p.T587del | In Frame Del (DEL) | VAF 18/88 reads (20%) | catalogued as rs753259536; called by pindel, varscan2
- DACT1 | c.1559del p.P520Rfs*60 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | catalogued as rs1481022066; called by mutect2, pindel, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 11/97 reads (11%) | catalogued as rs766714372; called by mutect2, varscan2
- DEFB116 | c.200G>T p.C67F | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68722176; called by muse, mutect2, varscan2
- DENND4B | c.2222G>A p.R741H | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1470438978, COSV63409792; called by muse, mutect2, varscan2
- DEPDC5 | c.1754A>G p.H585R | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.268); catalogued as rs1400872067, COSV56699805; called by muse, mutect2, varscan2
- DHX16 | c.2653T>C p.Y885H | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99527889; called by muse, mutect2
- DHX16 | c.2108G>A p.R703H | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs768833519, COSV53312776; called by muse, mutect2, varscan2
- DLGAP4 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs956282723, COSV59418698; called by muse, mutect2, varscan2
- DNAH9 | c.10024G>A p.A3342T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as rs746387468, COSV52354025; called by muse, mutect2, varscan2
- DNAI4 | c.89del p.K30Rfs*28 | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | catalogued as rs774662919; called by mutect2, pindel, varscan2
- DNAJA4 | c.221_223del p.E74del (on ENST00000343789; = p.E103del on NM_018602.3) | In Frame Del (DEL) | VAF 30/108 reads (28%) | catalogued as rs1385661050; called by pindel, varscan2
- DNAJB7 | c.257A>G p.Y86C | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.593); catalogued as COSV53423120; called by muse, mutect2
- DNM2 | c.455T>C p.I152T | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58963846; called by muse, mutect2, varscan2
- DNMT3L | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.25); catalogued as rs932565600, COSV54264592; called by muse, mutect2
- DOCK2 | c.5167C>T p.L1723F | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.454); catalogued as COSV56963253; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 21/107 reads (20%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK7 | c.2561G>A p.R854H | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs370921127, COSV52008080; called by muse, mutect2, varscan2
- DSCAM | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); catalogued as rs369481071, COSV68020002; called by muse, mutect2, varscan2
- DUSP3 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as rs200022065, COSV56824919; called by muse, mutect2, varscan2
- DYNC1H1 | c.8753A>G p.H2918R | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100794807; called by muse, varscan2
- EDA | c.929A>G p.Y310C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100999954; called by muse, mutect2, varscan2
- EDC4 | c.829A>G p.S277G | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as rs994648373, COSV62766319; called by muse, mutect2, varscan2
- EDEM2 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0.102); catalogued as rs757782647, COSV65713116; called by muse, mutect2, varscan2
- EFNA4 | c.535dup p.D179Gfs*65 | Frame Shift Ins (INS) | VAF 13/63 reads (21%) | catalogued as rs754580525; called by mutect2, varscan2
- EIF4G1 | c.2473C>T p.L825= (on ENST00000346169 / NM_198241.3; = p.L630= on NM_004953.5) | Splice Region (SNP) | VAF 28/80 reads (35%) | catalogued as rs367822197; called by muse, mutect2, varscan2
- ELAPOR1 | c.1340G>T p.G447V | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.668); catalogued as rs1416961565, COSV64040575; called by muse, mutect2, varscan2
- ELFN2 | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs146137658; called by muse, mutect2, varscan2
- EMID1 | c.1216G>A p.G406R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53323655; called by muse, mutect2, varscan2
- EMSY | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV58261249; called by muse, mutect2, varscan2
- ENO1 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); catalogued as COSV52304181; called by muse, mutect2, varscan2
- EPHA2 | c.1228T>A p.F410I | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64453399; called by muse, mutect2, varscan2
- EPM2AIP1 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | catalogued as COSV51619075; called by muse, mutect2, varscan2
- EPS8L1 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as rs567891670, COSV52382952; called by muse, mutect2, varscan2
- ERMP1 | c.1502C>A p.A501D | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV53037772; called by muse, mutect2, varscan2
- ESPNL | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs532111166, COSV58035292; called by muse, mutect2, varscan2
- EXD1 | c.11G>A p.S4N | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs772980179, COSV58157376; called by muse, mutect2, varscan2
- EXOC6 | c.1638+1G>A p.X546_splice | Splice Site (SNP) | VAF 7/39 reads (18%) | catalogued as COSV53325919; called by muse, mutect2, varscan2
- EXOC6B | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.052); catalogued as rs963525502, COSV55558308; called by muse, mutect2, varscan2
- F11 | c.915A>C p.E305D | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.548); catalogued as COSV53007221; called by muse, mutect2, varscan2
- F2 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as rs777785946, COSV61314647; called by muse, mutect2, varscan2
- F5 | c.817G>A p.G273S | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1328429966, COSV63124959; called by muse, mutect2, varscan2
- F9 | c.1006A>C p.I336L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.92); PolyPhen benign (0.009); catalogued as CX045848, COSV54380759; called by muse, mutect2, varscan2
- FAF1 | c.74A>G p.E25G | Missense Mutation (SNP) | VAF 49/226 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65639465; called by muse, mutect2, varscan2
- FAM174A | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.049); catalogued as COSV57063798; called by muse, mutect2, varscan2
- FAM193A | c.1421C>A p.P474H | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs779984639, COSV61194992; called by muse, mutect2, varscan2
- FAM214A | c.2042del p.N681Mfs*5 | Frame Shift Del (DEL) | VAF 35/97 reads (36%) | catalogued as rs762546731, COSV55927849; called by mutect2, varscan2
- FAM214B | c.1002dup p.S335Qfs*19 | Frame Shift Ins (INS) | VAF 8/34 reads (24%) | catalogued as rs775865641; called by mutect2, varscan2
- FAM220A | c.26G>A p.G9D | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV57626567; called by muse, mutect2, varscan2
- FAM78A | c.493A>G p.S165G | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs767363009, COSV99908503; called by mutect2, varscan2
- FBLN7 | c.1139G>A p.S380N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as COSV55616426; called by muse, mutect2, varscan2
- FBXL7 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.647); catalogued as rs755631121, COSV61647420; called by muse, mutect2, varscan2
- FBXO44 | c.29C>A p.P10H | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52354393; called by muse, mutect2
- FCRL3 | c.814del p.R272Gfs*3 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs1288807478; called by mutect2, pindel, varscan2
- FEZ1 | c.1142T>C p.L381P | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99630570; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FILIP1 | c.3625G>T p.G1209* | Nonsense Mutation (SNP) | VAF 27/90 reads (30%) | catalogued as COSV52732377; called by muse, mutect2, varscan2
- FKBP15 | c.1994del p.K665Rfs*9 | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | catalogued as rs774060142; called by mutect2, pindel, varscan2
- FMN2 | c.4219G>A p.A1407T | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60433466; called by muse, mutect2, varscan2
- FMOD | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.133); catalogued as COSV61610157; called by muse, mutect2, varscan2
- FNDC1 | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1400790835, COSV51934607; called by muse, mutect2, varscan2
- FNDC11 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs375992607; called by muse, mutect2, varscan2
- FNIP1 | c.2773dup p.I925Nfs*6 | Frame Shift Ins (INS) | VAF 36/188 reads (19%) | catalogued as rs1386424977; called by mutect2, varscan2
- FNIP1 | c.1226C>T p.T409M | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.576); catalogued as rs79530464, COSV57197091; called by muse, mutect2, varscan2
- FRK | c.797C>A p.P266Q | Missense Mutation (SNP) | VAF 67/266 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.697); catalogued as COSV73384019; called by muse, mutect2, varscan2
- FRMD4A | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs1292473177, COSV62266622; called by muse, mutect2, varscan2
- GAPVD1 | c.2525G>A p.R842K (on ENST00000394104; = p.R869K on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); catalogued as rs1471947888, COSV52923730; called by muse, mutect2, varscan2
- GAPVD1 | c.4384A>T p.M1462L (on ENST00000394104; = p.M1471L on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.635); catalogued as COSV52923745; called by muse, mutect2, varscan2
- GAS2L1 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs1270065441, COSV53330708; called by muse, mutect2
- GEN1 | c.797A>G p.H266R | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58055035; called by muse, mutect2, varscan2
- GHDC | c.386A>G p.Q129R | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs200346068, COSV56987012; called by mutect2, varscan2
- GIMAP6 | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs372777404, COSV61033706; called by muse, mutect2, varscan2
- GJA10 | c.616A>C p.T206P | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65355315; called by muse, mutect2, varscan2
- GLI3 | c.3101C>T p.A1034V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1446268237, COSV67895697; called by muse, mutect2
- GOLGB1 | c.2575A>G p.S859G | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV100510728; called by muse, mutect2
- GORASP2 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as COSV52201844; called by muse, mutect2
- GPALPP1 | c.499A>G p.R167G | Missense Mutation (SNP) | VAF 65/259 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62705961; called by muse, mutect2, varscan2
- GPALPP1 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 83/362 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781578978, COSV62705967; called by muse, mutect2, varscan2
- GPLD1 | c.760A>G p.M254V | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV57758171; called by muse, mutect2, varscan2
- GPR162 | c.1085G>A p.G362D (on ENST00000311268 / NM_019858.2; = p.G78D on NM_014449.2) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.915); catalogued as COSV51833862; called by muse, mutect2, varscan2
- GPR78 | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.073); catalogued as rs754162901, COSV66763208; called by muse, mutect2, varscan2
- GRIK2 | c.1577T>C p.V526A | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as COSV59742177; called by muse, mutect2
- GRIP2 | c.2463G>T p.Q821H (on ENST00000619221; = p.Q724H on NM_001080423.4) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99817258; called by muse, mutect2, varscan2
- GRIPAP1 | c.2207G>T p.S736I | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV54414459, COSV99502011; called by muse, mutect2, varscan2
- GRK6 | c.1123C>A p.L375M | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV62682295; called by muse, mutect2, varscan2
- GRK6 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV62682886; called by muse, mutect2, varscan2
- GRM8 | c.929G>T p.S310I | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV58832878; called by muse, mutect2, varscan2
- GSPT2 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.445); catalogued as COSV61214508; called by muse, mutect2, varscan2
- GSR | c.1039C>T p.L347= | Splice Region (SNP) | VAF 9/88 reads (10%) | catalogued as COSV55321154; called by muse, mutect2, varscan2
- GTDC1 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs748221458, COSV53996703; called by muse, mutect2, varscan2
- GUCY2F | c.2260G>A p.D754N | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV54303581; called by muse, mutect2, varscan2
- GUF1 | c.734dup p.P246Sfs*2 | Frame Shift Ins (INS) | VAF 22/126 reads (17%) | catalogued as rs1395184586; called by mutect2, pindel, varscan2
- H2AC12 | c.222_224del p.N74del | In Frame Del (DEL) | VAF 46/200 reads (23%) | catalogued as rs763337646; called by pindel, varscan2
- H2AZ1 | c.116C>A p.S39Y | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV56455370; called by muse, mutect2, varscan2
- H3C11 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 13/49 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); catalogued as rs769800748, COSV100137862; called by muse, mutect2, varscan2
- HAGHL | c.640del p.E214Rfs*15 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as rs747918697; called by mutect2, varscan2
- HAPLN4 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV52269942; called by muse, mutect2
- HDAC3 | c.838G>A p.V280I | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV59496236; called by muse, mutect2, varscan2
- HDAC5 | c.2793del p.I932Lfs*14 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as COSV52242263; called by mutect2, pindel, varscan2
- HELZ2 | c.6271G>A p.V2091I (on ENST00000467148 / NM_001037335.2; = p.V1522I on NM_033405.3) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs1024311463, COSV71296137; called by muse, mutect2, varscan2
- HGD | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.487); catalogued as COSV52198795; called by muse, mutect2, varscan2
- HGF | c.781C>A p.R261S | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as COSV55950085, COSV55950987; called by muse, mutect2, varscan2
- HLA-DRA | c.371T>C p.L124P | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as COSV66622812; called by muse, mutect2, varscan2
- HNRNPDL | c.1229del p.G410Vfs*25 | Frame Shift Del (DEL) | VAF 38/208 reads (18%) | catalogued as COSV99040410; called by mutect2, pindel, varscan2
- HNRNPL | c.1010dup p.P338Tfs*56 | Frame Shift Ins (INS) | VAF 16/48 reads (33%) | catalogued as rs767148651; called by mutect2, varscan2
- HOXD1 | c.842G>T p.R281M | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58923713; called by muse, mutect2, varscan2
- HP | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as rs558021408, COSV63326056; called by muse, mutect2, varscan2
- HS3ST5 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs775679934, COSV57140921; called by muse, mutect2, varscan2
- HYDIN | c.2034G>T p.E678D | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.026); catalogued as COSV55487874; called by muse, mutect2, varscan2
- IDE | c.1706del p.L569Cfs*45 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs771790236; called by mutect2, varscan2
- IFT140 | c.2110G>T p.G704C | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68489634; called by muse, mutect2, varscan2
- IGKV1-12 | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 46/285 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs765341545; called by muse, mutect2, varscan2
- IGSF9B | c.2648C>T p.T883M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs936090495, COSV58068794; called by muse, mutect2
- IL20RA | c.130A>G p.T44A | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as COSV57358660; called by muse, mutect2, varscan2
- ING5 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57979049; called by muse, mutect2, varscan2
- IP6K3 | c.998A>G p.Q333R | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.355); catalogued as COSV53390602; called by muse, mutect2, varscan2
- ITGB1 | c.955A>G p.I319V | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.398); catalogued as rs201869797, COSV56482750; called by muse, mutect2, varscan2
- ITPR2 | c.2606G>A p.R869Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs755838267, COSV67270575; called by muse, mutect2, varscan2
- KASH5 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs764513093, COSV71358056; called by muse, mutect2, varscan2
- KCNQ5 | c.2665G>A p.A889T | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as rs750000204, COSV59658622; called by muse, mutect2, varscan2
- KDM6B | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as rs764457029; called by muse, mutect2, varscan2
- KIAA0319L | c.399dup p.F134Ifs*6 | Frame Shift Ins (INS) | VAF 30/132 reads (23%) | catalogued as rs1383796563; called by mutect2, varscan2
- KIAA1549 | c.5276del p.P1759Rfs*66 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | catalogued as COSV54318123; called by mutect2, pindel, varscan2
- KIF20A | c.1990G>A p.A664T | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.025); catalogued as COSV67510007; called by muse, mutect2, varscan2
- KIT | c.605T>C p.L202P | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV99854100; called by muse, mutect2, varscan2
- KLHL34 | c.1673C>A p.P558H | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.628); catalogued as COSV65279567; called by muse, mutect2, varscan2
- KLKB1 | c.418dup p.R140Kfs*5 | Frame Shift Ins (INS) | VAF 27/142 reads (19%) | catalogued as rs755680952; called by mutect2, pindel, varscan2
- KRT75 | c.1456G>A p.G486S | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as rs148114656; called by muse, mutect2, varscan2
- KRT75 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as rs779742513, COSV52871179, COSV52873294; called by muse, mutect2, varscan2
- KRT9 | c.1567G>T p.G523* | Nonsense Mutation (SNP) | VAF 33/220 reads (15%) | catalogued as COSV55853640; called by muse, mutect2, varscan2
- KRTAP5-7 | c.47del p.G16Afs*159 | Frame Shift Del (DEL) | VAF 62/284 reads (22%) | catalogued as COSV68325097; called by mutect2, pindel, varscan2
- LAMA1 | c.2140G>T p.G714C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67538654; called by muse, mutect2, varscan2
- LCT | c.4540C>T p.R1514W | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs752406025, COSV51551054; called by muse, mutect2, varscan2
- LIN54 | c.1807C>T p.R603* | Nonsense Mutation (SNP) | VAF 47/177 reads (27%) | catalogued as COSV61200575; called by muse, mutect2, varscan2
- LONRF2 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs751581769, COSV66539733; called by muse, mutect2, varscan2
- LRP1 | c.13112C>T p.A4371V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV99675611; called by muse, mutect2
- LRP1B | c.8956T>C p.Y2986H | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.03); catalogued as rs370751086; called by muse, mutect2, varscan2
- LRRC23 | c.306C>A p.H102Q | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as COSV50390037; called by muse, varscan2
- LRRC45 | c.1238-1G>T p.X413_splice | Splice Site (SNP) | VAF 28/73 reads (38%) | catalogued as COSV60711737; called by muse, mutect2, varscan2
- LRRCC1 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 30/145 reads (21%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.499); catalogued as rs1384828666, COSV64482791; called by muse, mutect2, varscan2
- LRRK2 | c.1639C>A p.L547I | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100110020; called by muse, mutect2, varscan2
- LTBP4 | c.3334G>T p.G1112C (on ENST00000308370 / NM_001042544.1; = p.G1075C on NM_003573.2) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52583213; called by muse, mutect2, varscan2
- LY75 | c.4235del p.K1412Rfs*2 | Frame Shift Del (DEL) | VAF 24/84 reads (29%) | catalogued as rs1301982151; called by mutect2, varscan2
- MAP1LC3A | c.42C>T p.A14= | Splice Region (SNP) | VAF 4/40 reads (10%) | catalogued as COSV54163464; called by muse, mutect2
- MAP2K7 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67607853; called by muse, mutect2, varscan2
- MAPK8IP2 | c.1765A>G p.S589G | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs770751117, COSV99151213; called by muse, mutect2, varscan2
- MBTPS1 | c.2653C>T p.R885C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.547); catalogued as rs1424613321, COSV58571095; called by muse, mutect2, varscan2
- MCC | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.982); catalogued as rs369421434; called by muse, mutect2, varscan2
- MCCD1 | c.31T>C p.Y11H | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV66019469; called by muse, mutect2, varscan2
- MCM5 | c.1590+2T>C p.X530_splice | Splice Site (SNP) | VAF 8/39 reads (21%) | catalogued as COSV53349447; called by muse, mutect2, varscan2
- MDC1 | c.5197C>T p.L1733F | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.642); catalogued as rs747463459, COSV64524987; called by muse, mutect2, varscan2
- ME3 | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762509717, COSV60165117; called by muse, mutect2, varscan2
- MED15 | c.1886T>C p.I629T (on ENST00000263205 / NM_001003891.3; = p.I589T on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV53030004; called by muse, mutect2, varscan2
- MEGF8 | c.6428del p.G2143Afs*20 (on ENST00000251268 / NM_001271938.2; = p.G2076Afs*20 on NM_001410.3) | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | catalogued as rs1258909672; called by mutect2, pindel, varscan2
- MFN2 | c.306del p.F102Lfs*11 | Frame Shift Del (DEL) | VAF 38/149 reads (26%) | catalogued as rs777012596; called by mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MISP | c.722A>G p.N241S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as COSV99296785; called by muse, mutect2
- MORC2 | c.2441C>T p.A814V (on ENST00000397641 / NM_001303256.3; = p.A752V on NM_014941.3) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53199448; called by muse, mutect2, varscan2
- MPDZ | c.5016G>T p.W1672C | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV59918980; called by muse, mutect2, varscan2
- MPPED1 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.051); catalogued as COSV68838406; called by muse, mutect2, varscan2
- MRPL39 | c.760C>A p.L254I | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV56261032; called by muse, mutect2, varscan2
- MS4A5 | c.448T>C p.S150P | Missense Mutation (SNP) | VAF 30/301 reads (10%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.5); catalogued as COSV55741158; called by muse, mutect2, varscan2
- MSTN | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as rs771117616, COSV53621168; called by muse, mutect2, varscan2
- MTMR4 | c.3575C>T p.T1192I | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV60201031; called by muse, mutect2
- MTO1 | c.2144G>T p.R715I (on ENST00000370300 / NM_133645.3; = p.R690I on NM_012123.4) | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV64774011; called by muse, mutect2, varscan2
- MTSS2 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as rs746132522, COSV55381124; called by muse, mutect2
- MUC16 | c.32528del p.F10843Sfs*11 | Frame Shift Del (DEL) | VAF 25/145 reads (17%) | catalogued as COSV67467225; called by mutect2, pindel, varscan2
- MUC4 | c.13100T>C p.I4367T (on ENST00000463781 / NM_018406.7; = p.I131T on NM_004532.6) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV57784177; called by muse, mutect2, varscan2
- MUC5B | c.3673G>A p.G1225R | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs763902961, COSV71590870; called by muse, mutect2, varscan2
- MYLK | c.468G>A p.W156* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as rs1560156324, COSV60612295; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO10 | c.3674del p.G1225Afs*22 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs760302326; called by mutect2, varscan2
- MYO1A | c.3098A>G p.K1033R | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.167); catalogued as rs1263862652, COSV55653801; called by mutect2, varscan2
- MYO3B | c.1383T>A p.N461K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58705707; called by muse, mutect2, varscan2
- MYO9B | c.3317G>T p.S1106I | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.163); catalogued as COSV68279869; called by muse, mutect2, varscan2
- NBEA | c.8068C>T p.R2690C | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV59791368; called by muse, mutect2, varscan2
- NCOA3 | c.3611C>T p.A1204V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as rs758545305, COSV59069544; called by muse, mutect2, varscan2
- NDST3 | c.2282del p.P761Hfs*5 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | catalogued as COSV56622489; called by mutect2, pindel, varscan2
- NDUFV2 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 15/172 reads (9%) | catalogued as rs768703151, COSV59187380; called by muse, mutect2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 13/71 reads (18%) | catalogued as rs759081520; called by mutect2, pindel
- NEU3 | c.706A>G p.I236V | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.101); catalogued as rs371627063; called by muse, mutect2, varscan2
- NEURL4 | c.4206-2A>G p.X1402_splice | Splice Site (SNP) | VAF 18/51 reads (35%) | catalogued as COSV59750377; called by muse, mutect2, varscan2
- NEUROD2 | c.595C>A p.P199T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56911166; called by muse, mutect2, varscan2
- NIT1 | c.415A>G p.T139A | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.012); catalogued as rs759711881, COSV63501862; called by muse, mutect2, varscan2
- NLRC5 | c.2219T>C p.L740P | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.285); catalogued as rs1205761884, COSV52656876; called by muse, mutect2, varscan2
- NLRP5 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0.013); catalogued as COSV66765249; called by muse, mutect2, varscan2
- NMBR | c.596T>C p.I199T | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as COSV57801584; called by muse, mutect2, varscan2
- NOP9 | c.169C>A p.L57M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV55384391; called by muse, mutect2, varscan2
- NPC1 | c.3824T>A p.L1275H | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV99340074; called by muse, mutect2
- NPRL3 | c.640T>C p.S214P (on ENST00000611875 / NM_001077350.3; = p.S189P on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as COSV101302037; called by muse, mutect2, varscan2
- NRG3 | c.811A>G p.S271G | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.304); catalogued as COSV64567024; called by muse, mutect2, varscan2
- NUDT7 | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs76004401; called by muse, mutect2, varscan2
- NUP205 | c.1012A>G p.R338G | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53660537; called by muse, mutect2, varscan2
- NYAP2 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs774734033, COSV56004596; called by muse, mutect2, varscan2
- OBSCN | c.7022G>A p.G2341D | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV52783138; called by muse, mutect2, varscan2
- OR10AG1 | c.22T>G p.F8V | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV100400057; called by muse, mutect2, varscan2
- OR52E4 | c.322A>G p.M108V | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV57625109; called by muse, mutect2, varscan2
- OTUB1 | c.280C>T p.R94W | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565186502, COSV55361661; called by muse, mutect2, varscan2
- P2RX7 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.489); catalogued as rs149639375, COSV55855706; called by mutect2, varscan2
- PABPC4 | c.877-2A>G p.X293_splice | Splice Site (SNP) | VAF 8/64 reads (13%) | catalogued as COSV100790874; called by mutect2, varscan2
- PAX5 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63907118; called by muse, mutect2, varscan2
- PBXIP1 | c.113T>C p.L38P | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100870066; called by muse, mutect2, varscan2
- PCDH10 | c.360del p.S121Lfs*7 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs759095467; called by mutect2, pindel
- PCDHA1 | c.1937G>A p.R646H | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.056); catalogued as COSV65374824; called by muse, mutect2
- PCNT | c.3961G>A p.A1321T | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs149718202; called by muse, mutect2, varscan2
- PCNT | c.5432G>A p.R1811H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs769452431, COSV64029276; called by muse, mutect2, varscan2
- PDE6A | c.379A>G p.M127V | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV54928135; called by muse, mutect2, varscan2
- PDE9A | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0.015); catalogued as COSV52323115; called by muse, mutect2, varscan2
- PDXDC1 | c.1837G>C p.V613L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV55074595; called by muse, mutect2, varscan2
- PDZD7 | c.1214G>A p.G405D | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs1327483871, COSV64646517; called by muse, mutect2
- PEBP4 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV56467683; called by muse, mutect2
- PIANP | c.844C>A p.L282M | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.539); catalogued as COSV57708047; called by muse, mutect2
- PIK3C2G | c.2516del p.N839Mfs*16 (on ENST00000676171; = p.N798Mfs*16 on NM_004570.5) | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | catalogued as rs1229278001; called by mutect2, pindel
- PIK3R5 | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757235159, COSV52652885; called by muse, mutect2, varscan2
- PIWIL1 | c.1625T>C p.L542S | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV55347701; called by muse, mutect2, varscan2
- PKD1 | c.5648C>T p.A1883V | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779745348, COSV51918061; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PLA2R1 | c.271G>T p.G91C | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51780305; called by muse, mutect2, varscan2
- PLCB3 | c.2206C>T p.Q736* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV54189301; called by muse, mutect2, varscan2
- PLCG2 | c.685A>T p.I229F | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.276); catalogued as COSV100842252; called by muse, mutect2
- PLD1 | c.2225T>C p.V742A | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV60569164; called by muse, mutect2
- PLEKHG3 | c.2596G>A p.V866I (on ENST00000394691; = p.V922I on NM_001308147.2) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs371587777; called by muse, mutect2, varscan2
- PLEKHG4B | c.1790G>A p.R597H (on ENST00000283426; = p.R953H on NM_052909.5) | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs116369175; called by muse, mutect2, varscan2
- PLEKHG6 | c.479G>A p.C160Y | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.642); catalogued as rs1378952151, COSV50602323; called by muse, mutect2, varscan2
- PLS1 | c.579+2T>C p.X193_splice | Splice Site (SNP) | VAF 40/176 reads (23%) | catalogued as rs376720877; called by muse, mutect2, varscan2
- PLXNA1 | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.768); catalogued as rs372378194; called by muse, mutect2, varscan2
- PLXNA1 | c.4509G>T p.L1503= | Splice Region (SNP) | VAF 8/97 reads (8%) | catalogued as COSV52527550; called by muse, mutect2
- PLXNB1 | c.2380C>T p.P794S | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as COSV56490679; called by muse, mutect2, varscan2
- PMM1 | c.340A>G p.S114G | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV53448019; called by muse, mutect2, varscan2
- PNPLA6 | c.2582C>T p.T861M (on ENST00000414982 / NM_001166111.2; = p.T813M on NM_006702.5) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55379490; called by muse, mutect2, varscan2
- POGK | c.1397G>T p.G466V | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); catalogued as COSV63311776; called by muse, mutect2
- POLD1 | c.1279C>A p.L427I | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0.01); catalogued as COSV70955524; called by muse, mutect2, varscan2
- POLM | c.290dup p.A98Sfs*73 | Frame Shift Ins (INS) | VAF 10/42 reads (24%) | catalogued as rs745933237; called by mutect2, varscan2
- POLR1B | c.448A>T p.N150Y | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV54499235; called by muse, mutect2
- POLRMT | c.3097G>A p.V1033I | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1804752, COSV52115388; called by muse, mutect2, varscan2
- PPP2R2B | c.445C>T p.R149W (on ENST00000394409; = p.R215W on NM_181674.2) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs778242934, COSV60766984; called by muse, mutect2
- PRAM1 | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1027874916, COSV55314232; called by muse, mutect2, varscan2
- PRAM1 | c.770C>A p.P257H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV55314241; called by muse, mutect2, varscan2
- PREP | c.1327G>A p.E443K (on ENST00000369110; = p.E509K on NM_002726.5) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1464752004, COSV100963895; called by muse, mutect2, varscan2
- PRKAA1 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.891); catalogued as rs1175516950, COSV57182922; called by muse, mutect2, varscan2
- PRKDC | c.7856G>A p.R2619H | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.28); catalogued as rs138740003, COSV58054728; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKDC | c.6860C>T p.P2287L | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV100041109, COSV58054732; called by muse, mutect2, varscan2
- PRPF38B | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 15/258 reads (6%) | catalogued as COSV100898263; called by muse, mutect2
- PSKH2 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201080415; called by muse, mutect2, varscan2
- PSMD13 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.332); catalogued as rs372085323; called by muse, mutect2, varscan2
- PTCD1 | c.246C>A p.D82E | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV52857862, COSV52858146; called by muse, varscan2
- PTCHD3 | c.2057dup p.N686Kfs*6 | Frame Shift Ins (INS) | VAF 20/77 reads (26%) | catalogued as rs750923568; called by mutect2, varscan2
- PYGL | c.1700A>G p.Q567R | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs753383533, COSV99368555; called by muse, mutect2, varscan2
- QRICH1 | c.643A>G p.T215A | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV62615943; called by muse, mutect2
- RAB11FIP1 | c.466A>G p.S156G | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54760804; called by muse, mutect2, varscan2
- RASA3 | c.1478C>T p.S493F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61868321; called by muse, mutect2, varscan2
- RASL10B | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs776545435; called by muse, varscan2
- RBBP6 | c.2186G>A p.R729Q | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as rs1037290084, COSV60505756; called by muse, mutect2, varscan2
- RBM3 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs782287047, COSV63202609; called by muse, mutect2, varscan2
- RCN3 | c.119T>C p.L40P | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54542401; called by muse, mutect2, varscan2
- RCOR3 | c.1143G>T p.E381D | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV65365986; called by muse, mutect2, varscan2
- RECQL | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs202110155, COSV69658591; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REPS1 | c.1425C>T p.S475= | Splice Region (SNP) | VAF 39/147 reads (27%) | catalogued as rs141996588; called by muse, mutect2, varscan2
- RFTN1 | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as rs765769545, COSV61919987; called by muse, mutect2, varscan2
- RFX4 | c.1535C>T p.S512L (on ENST00000392842 / NM_213594.3; = p.S418L on NM_032491.6) | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.32); catalogued as rs769992690, COSV57575652; called by muse, mutect2, varscan2
- RFXAP | c.359del p.G120Afs*18 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | catalogued as rs1224857205; called by mutect2, pindel, varscan2
- RHBDD3 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.831); catalogued as rs1370759549, COSV99328506; called by muse, mutect2, varscan2
- RIN1 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs141887009; called by muse, mutect2, varscan2
- ROBO2 | c.3233del p.P1078Qfs*95 | Frame Shift Del (DEL) | VAF 40/164 reads (24%) | catalogued as rs745519558, COSV100168583; called by mutect2, varscan2
- RPS6KA2 | c.1953G>T p.K651N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.302); catalogued as COSV55822173; called by muse, mutect2
- RPS8 | c.392C>A p.P131H | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV63234450; called by muse, mutect2
- RSL1D1 | c.134C>T p.T45M | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs369583738; called by muse, mutect2, varscan2
- RTKN2 | c.546A>C p.E182D | Missense Mutation (SNP) | VAF 122/504 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as COSV59522691; called by muse, mutect2, varscan2
- SAMD4A | c.2149A>G p.T717A | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99200635; called by muse, mutect2
- SAMHD1 | c.1682del p.K561Rfs*35 (on ENST00000262878 / NM_001363729.2; = p.K596Rfs*35 on NM_015474.4) | Frame Shift Del (DEL) | VAF 45/210 reads (21%) | catalogued as rs1215993198; called by mutect2, pindel, varscan2
- SBF1 | c.3228del p.S1077Afs*28 | Frame Shift Del (DEL) | VAF 23/80 reads (29%) | catalogued as rs771002611; called by mutect2, pindel, varscan2
- SCAF4 | c.749del p.P250Hfs*96 | Frame Shift Del (DEL) | VAF 58/225 reads (26%) | catalogued as COSV54589079; called by mutect2, pindel, varscan2
- SDK2 | c.4246C>T p.R1416C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs558804353, COSV66187800; called by muse, mutect2, varscan2
- SEMA3G | c.2252G>T p.R751M | Missense Mutation (SNP) | VAF 62/256 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99202314; called by muse, mutect2, varscan2
- SFTA2 | c.34A>G p.T12A | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.018); catalogued as COSV62997750; called by muse, mutect2, varscan2
- SIGLEC1 | c.1123C>A p.L375I | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52465511; called by muse, mutect2
- SIGLEC14 | c.606del p.R203Gfs*13 | Frame Shift Del (DEL) | VAF 117/467 reads (25%) | catalogued as rs1242931678; called by mutect2, varscan2
- SIPA1 | c.758G>A p.S253N | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.035); catalogued as COSV100856332; called by muse, mutect2, varscan2
- SLC23A1 | c.268G>A p.V90M | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774361660, COSV62296777; called by muse, mutect2, varscan2
- SLC30A2 | c.464G>A p.S155N | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.612); catalogued as rs1176649861, COSV65332849; called by muse, mutect2, varscan2
- SLC30A5 | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.437); catalogued as rs145568710; called by muse, mutect2
- SLC39A2 | c.210G>T p.E70D | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.253); catalogued as COSV53869856; called by muse, mutect2, varscan2
- SLC39A4 | c.798G>T p.W266C (on ENST00000301305 / NM_001374839.1; = p.W241C on NM_017767.3) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52779334; called by muse, mutect2
- SLC5A2 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1555495710, COSV100392933, COSV57892238; called by muse, mutect2, varscan2
- SLC9B2 | c.1019C>T p.T340I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.162); catalogued as COSV60019794; called by muse, mutect2, varscan2
- SLFN13 | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 75/316 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); catalogued as COSV53193924; called by muse, mutect2, varscan2
- SMG6 | c.2813G>A p.R938H | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.12); catalogued as rs368650142; called by muse, mutect2, varscan2
- SORBS2 | c.3130dup p.E1044Gfs*8 (on ENST00000284776 / NM_021069.5; = p.E610Gfs*8 on NM_003603.6) | Frame Shift Ins (INS) | VAF 20/96 reads (21%) | catalogued as rs772549791, COSV52990153; called by mutect2, varscan2
- SP3 | c.1966A>G p.M656V | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV59468049; called by muse, mutect2, varscan2
- SPDYA | c.362T>C p.I121T | Missense Mutation (SNP) | VAF 18/319 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.053); catalogued as COSV61856127; called by muse, mutect2
- SPECC1 | c.2624G>A p.R875Q | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as rs758717249, COSV54959515; called by muse, mutect2, varscan2
- SPNS3 | c.199+2T>C p.X67_splice | Splice Site (SNP) | VAF 14/81 reads (17%) | catalogued as COSV100336955; called by muse, mutect2, varscan2
- SRRT | c.1889A>G p.Y630C | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53818253; called by muse, mutect2, varscan2
- STEAP4 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750091751, COSV57328060; called by muse, mutect2, varscan2
- SULT1B1 | c.575del p.L192Cfs*6 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | catalogued as rs1316574540; called by mutect2, pindel, varscan2
- SYNE1 | c.9767A>G p.Q3256R (on ENST00000367255 / NM_182961.4; = p.Q3263R on NM_033071.3) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs201760281, COSV99562082; called by muse, mutect2, varscan2
- SYNE1 | c.8494dup p.M2832Nfs*53 (on ENST00000367255 / NM_182961.4; = p.M2839Nfs*53 on NM_033071.3) | Frame Shift Ins (INS) | VAF 26/128 reads (20%) | catalogued as rs1005304459; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- SYNE1 | c.2188A>G p.K730E (on ENST00000367255 / NM_182961.4; = p.K737E on NM_033071.3) | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV99562086; called by muse, mutect2
- TAF1C | c.1243-2A>G p.X415_splice | Splice Site (SNP) | VAF 9/70 reads (13%) | catalogued as COSV100499543; called by mutect2, varscan2
- TAOK3 | c.1771C>T p.H591Y | Missense Mutation (SNP) | VAF 93/479 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.487); catalogued as COSV66826220; called by muse, mutect2, varscan2
- TAS1R2 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as rs779157147, COSV64745398; called by muse, mutect2, varscan2
- TBC1D16 | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs140972222; called by muse, mutect2, varscan2
- TBC1D25 | c.677A>G p.H226R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV100952141; called by muse, mutect2
- TBC1D4 | c.2034-2A>C p.X678_splice | Splice Site (SNP) | VAF 33/126 reads (26%) | catalogued as rs1343903985, COSV66489655; called by muse, mutect2, varscan2
- TBL1XR1 | c.1183T>C p.Y395H | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1323521798, COSV70499467, COSV70501617; called by muse, mutect2, varscan2
- TCERG1 | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV57036792; called by muse, mutect2, varscan2
- TCF12 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs772390979, COSV51008827; called by muse, mutect2, varscan2
- TCF3 | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 33/133 reads (25%) | catalogued as COSV53649444; called by muse, mutect2, varscan2
- TECRL | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 25/342 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs761513125, COSV101168848, COSV67085217; called by muse, mutect2
- TGIF2 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV65836580; called by muse, mutect2, varscan2
- TLN2 | c.4664A>G p.D1555G | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.16); catalogued as COSV100168843; called by muse, varscan2
- TLR7 | c.1521del p.F507Lfs*16 | Frame Shift Del (DEL) | VAF 37/90 reads (41%) | catalogued as rs764545107; called by mutect2, pindel, varscan2
- TMC6 | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs148239603, COSV59809459; called by muse, mutect2
- TMEM161A | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as rs1291412772, COSV50776438; called by muse, mutect2, varscan2
- TMEM190 | c.179G>A p.C60Y | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52581917; called by muse, mutect2, varscan2
- TMPRSS9 | c.1352G>A p.R451H (on ENST00000648592; = p.R417H on NM_182973.2) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs145109209; called by muse, mutect2, varscan2
- TONSL | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1170418104, COSV68048479; called by muse, mutect2, varscan2
- TOX2 | c.814G>A p.A272T (on ENST00000358131 / NM_001098798.2; = p.A221T on NM_032883.3) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs370568497; called by muse, mutect2, varscan2
- TRIM32 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1025366788; called by muse, mutect2
- TRIM4 | c.1376_1378del p.F459del | In Frame Del (DEL) | VAF 6/51 reads (12%) | catalogued as rs1382015660; called by mutect2, pindel
- TRIM48 | c.299T>C p.L100P | Missense Mutation (SNP) | VAF 295/1170 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV70161812; called by muse, mutect2, varscan2
- TRIM50 | c.332G>A p.C111Y | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52720696; called by muse, mutect2
- TRIM55 | c.784G>C p.V262L | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV52546908, COSV99396800; called by muse, mutect2, varscan2
- TRIM61 | c.449C>A p.P150Q | Missense Mutation (SNP) | VAF 81/593 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as COSV100255963; called by muse, mutect2, varscan2
- TRIM71 | c.2420G>A p.R807H | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as rs979021897, COSV67471357; called by muse, mutect2, varscan2
- TRIML2 | c.632A>G p.Y211C | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV58716768; called by muse, mutect2, varscan2
- TRMT5 | c.1178T>G p.I393R | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV54203774; called by muse, mutect2, varscan2
- TRPC6 | c.2379del p.G794Vfs*8 | Frame Shift Del (DEL) | VAF 20/87 reads (23%) | catalogued as rs757567055; called by mutect2, pindel, varscan2
- TRPC7 | c.1499A>G p.Q500R | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV100725677; called by muse, mutect2, varscan2
- TSC22D1 | c.1651T>C p.S551P | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs779732270, COSV71775783; called by muse, mutect2, varscan2
- TTN | c.76006G>A p.V25336I (on ENST00000591111; = p.V17912I on NM_003319.4) | Missense Mutation (SNP) | VAF 42/278 reads (15%) | PolyPhen benign (0.033); catalogued as COSV100610147; called by muse, mutect2, varscan2
- TUBB2A | c.619C>A p.L207M | Missense Mutation (SNP) | VAF 135/505 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV61319141; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as rs760251146; called by mutect2, varscan2
- TVP23C | c.94A>G p.R32G | Missense Mutation (SNP) | VAF 127/478 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99846829; called by muse, mutect2, varscan2
- UBR1 | c.3815T>C p.F1272S | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as COSV99317129; called by muse, mutect2, varscan2
- UBR4 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV64391426; called by muse, mutect2, varscan2
- UGCG | c.1094del p.L365Cfs*9 | Frame Shift Del (DEL) | VAF 25/104 reads (24%) | catalogued as rs1243652090; called by mutect2, pindel, varscan2
- UGT1A4 | c.460G>A p.V154I | Missense Mutation (SNP) | VAF 83/298 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs762367100, COSV100531094, COSV59389879, COSV59396877; called by muse, mutect2, varscan2
- UGT8 | c.440T>C p.I147T | Missense Mutation (SNP) | VAF 97/451 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV60418512, COSV60422004; called by muse, mutect2, varscan2
- UNC13B | c.2888G>A p.R963Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as rs147799499; called by muse, mutect2, varscan2
- URGCP | c.1172G>A p.R391H (on ENST00000453200 / NM_001077663.3; = p.R382H on NM_017920.4) | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.847); catalogued as rs1449282721, COSV56248527; called by muse, mutect2, varscan2
- USP1 | c.2225A>G p.E742G | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as COSV52008067; called by muse, mutect2, varscan2
- USP16 | c.112A>G p.K38E | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV100537916; called by muse, mutect2
- USP40 | c.386T>C p.M129T | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.137); catalogued as COSV52482240; called by muse, mutect2, varscan2
- UTP18 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs1166889272, COSV56583654; called by muse, mutect2, varscan2
- UTS2R | c.784G>T p.G262C | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV57453097; called by muse, varscan2
- VCAN | c.9883G>A p.A3295T | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54107244; called by muse, mutect2, varscan2
- VPS13B | c.6907C>T p.R2303W | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs781460252, COSV62143087; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13B | c.8777G>T p.G2926V | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.283); catalogued as COSV62145137; called by muse, mutect2, varscan2
- VPS37B | c.480G>T p.Q160H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV53442122; called by muse, mutect2, varscan2
- VPS72 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs776748360, COSV63167529; called by muse, mutect2, varscan2
- VTN | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.027); catalogued as rs782250181, COSV56873721; called by muse, mutect2, varscan2
- WARS2 | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.581); catalogued as COSV52479165; called by muse, mutect2, varscan2
- WDR45 | c.941G>A p.R314H (on ENST00000376372 / NM_001029896.2; = p.R315H on NM_007075.3) | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs782736017, COSV59875954; called by muse, mutect2, varscan2
- WEE2 | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs956821646, COSV66878706; called by muse, mutect2, varscan2
- WIZ | c.5407C>T p.R1803W (on ENST00000673675 / NM_001371589.1; = p.R708W on NM_021241.3) | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs199534121; called by muse, mutect2, varscan2
- WNK2 | c.5615A>T p.D1872V (on ENST00000297954 / NM_001282394.1; = p.D1835V on NM_006648.3) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV52945273; called by muse, mutect2, varscan2
- XAGE5 | c.122A>G p.Q41R | Missense Mutation (SNP) | VAF 77/163 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs782072151, COSV100657812; called by muse, mutect2, varscan2
- XKRX | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60708340; called by muse, mutect2
- XRCC1 | c.34T>C p.C12R | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV53450408; called by muse, mutect2, varscan2
- XRCC3 | c.975del p.S326Pfs*43 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | catalogued as rs770137120; called by mutect2, pindel, varscan2
- XRCC3 | c.774+2T>C p.X258_splice | Splice Site (SNP) | VAF 15/56 reads (27%) | catalogued as COSV57977366; called by muse, mutect2, varscan2
- YEATS2 | c.2960C>T p.T987M | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs377227996, COSV59366890; called by muse, mutect2, varscan2
- ZBTB43 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.778); catalogued as rs1300483453, COSV65094859; called by muse, mutect2, varscan2
- ZDHHC16 | c.269T>C p.L90P | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1281999138, COSV61749228; called by muse, mutect2, varscan2
- ZDHHC3 | c.310del p.A104Qfs*17 | Frame Shift Del (DEL) | VAF 18/87 reads (21%) | catalogued as COSV56101612; called by mutect2, pindel, varscan2
- ZKSCAN4 | c.1624del p.T542Lfs*27 | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | catalogued as rs757603403; called by mutect2, pindel
- ZNF157 | c.527A>G p.N176S | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV65659096; called by muse, mutect2, varscan2
- ZNF207 | c.168+2T>C p.X56_splice | Splice Site (SNP) | VAF 24/93 reads (26%) | catalogued as COSV58300144; called by muse, mutect2, varscan2
- ZNF236 | c.2810T>C p.L937S | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53490101; called by muse, mutect2, varscan2
- ZNF438 | c.1772G>T p.R591M | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59195982; called by muse, mutect2, varscan2
- ZNF48 | c.745del p.R249Dfs*43 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | catalogued as rs780189754; called by mutect2, pindel, varscan2
- ZNF572 | c.1336G>T p.G446C | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100073931; called by muse, mutect2, varscan2
- ZNF600 | c.689T>C p.V230A | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV57743045; called by muse, mutect2, varscan2
- ZNF644 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV61348605; called by muse, varscan2
- ZNF746 | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.212); catalogued as rs750407943, COSV61407042; called by muse, mutect2, varscan2
- ZRANB3 | c.1524A>C p.E508D | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV51504423; called by muse, mutect2
- ZSCAN1 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.394); catalogued as rs1038549774, COSV99991640; called by muse, mutect2
- ZZZ3 | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 24/100 reads (24%) | catalogued as rs1023547086, COSV66233425; called by muse, mutect2, varscan2
- ABI3BP | c.2081del p.K694Sfs*41 | Frame Shift Del (DEL) | VAF 30/314 reads (10%) | called by mutect2, pindel, varscan2
- ACTL7A | c.67del p.L23Cfs*11 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel, varscan2
- ACTN4 | c.1658A>G p.D553G | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- AHNAK2 | c.2947del p.D983Tfs*9 | Frame Shift Del (DEL) | VAF 20/122 reads (16%) | called by mutect2, pindel, varscan2
- AKAP12 | c.4382del p.N1461Mfs*26 | Frame Shift Del (DEL) | VAF 7/59 reads (12%) | called by pindel, varscan2
- AKT1S1 | c.426del p.F143Sfs*14 (on ENST00000344175 / NM_001098633.4; = p.F163Sfs*14 on NM_032375.5) | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | called by mutect2, pindel, varscan2
- ATRIP | c.1033del p.L345Cfs*31 | Frame Shift Del (DEL) | VAF 20/79 reads (25%) | called by mutect2, pindel, varscan2
- AVPR1A | c.1053del p.F351Lfs*19 | Frame Shift Del (DEL) | VAF 48/232 reads (21%) | called by mutect2, pindel, varscan2
- BACH2 | c.819dup p.Q274Afs*3 | Frame Shift Ins (INS) | VAF 16/72 reads (22%) | called by mutect2, pindel, varscan2
- BIRC6 | c.5207del p.P1736Qfs*17 | Frame Shift Del (DEL) | VAF 35/106 reads (33%) | called by mutect2, pindel, varscan2
- BRINP2 | c.780dup p.Q261Sfs*6 | Frame Shift Ins (INS) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- C9 | c.423del p.C142Afs*6 | Frame Shift Del (DEL) | VAF 17/76 reads (22%) | called by mutect2, pindel, varscan2
- CALR | c.791del p.P264Qfs*2 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- CAVIN1 | c.112del p.A38Pfs*6 | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | called by mutect2, pindel, varscan2
- CBX1 | c.543del p.D182Mfs*30 | Frame Shift Del (DEL) | VAF 14/164 reads (9%) | called by mutect2, pindel
- CCNL1 | c.487del p.R163Gfs*6 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | called by mutect2, pindel, varscan2
- CDKN2AIP | c.395G>C p.S132T | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- CHD3 | c.2292del p.L765* | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | called by mutect2, pindel, varscan2
- CLTCL1 | c.756dup p.P253Sfs*7 | Frame Shift Ins (INS) | VAF 17/164 reads (10%) | called by mutect2, pindel, varscan2
- COL19A1 | c.1753del p.S585Afs*8 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- CSMD1 | c.4985dup p.V1663Rfs*15 (on ENST00000520002; = p.V1662Rfs*15 on NM_033225.6) | Frame Shift Ins (INS) | VAF 13/49 reads (27%) | called by mutect2, pindel, varscan2
- DDX21 | c.350del p.N117Mfs*9 | Frame Shift Del (DEL) | VAF 54/245 reads (22%) | called by mutect2, pindel, varscan2
- DENND4C | c.5176del p.R1726Dfs*12 (on ENST00000434457 / NM_001330640.2; = p.R1677Dfs*12 on NM_017925.7) | Frame Shift Del (DEL) | VAF 23/110 reads (21%) | called by mutect2, pindel, varscan2
- DPP10 | c.1312del p.I438Ffs*4 | Frame Shift Del (DEL) | VAF 37/172 reads (22%) | called by mutect2, pindel, varscan2
- ECM1 | c.506del p.P169Lfs*9 | Frame Shift Del (DEL) | VAF 8/51 reads (16%) | called by mutect2, pindel, varscan2
- ELK4 | c.1075dup p.S359Ffs*37 | Frame Shift Ins (INS) | VAF 18/94 reads (19%) | called by mutect2, varscan2
- EML1 | c.568T>C p.F190L | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.213); called by muse, mutect2
- FAM120A | c.1650del p.V551Sfs*6 | Frame Shift Del (DEL) | VAF 30/153 reads (20%) | called by mutect2, pindel, varscan2
- FAM20A | c.622del p.A208Hfs*8 | Frame Shift Del (DEL) | VAF 33/131 reads (25%) | called by mutect2, pindel, varscan2
- FAS | c.403dup p.C135Lfs*2 | Frame Shift Ins (INS) | VAF 38/127 reads (30%) | called by mutect2, varscan2
- FAT3 | c.7727A>G p.D2576G | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBXL6 | c.772-3del | Splice Region (DEL) | VAF 8/47 reads (17%) | called by mutect2, pindel, varscan2
- GJB2 | c.671dup p.P225Afs*32 | Frame Shift Ins (INS) | VAF 16/64 reads (25%) | called by mutect2, pindel, varscan2
- GLIS1 | c.1657del p.L553Cfs*97 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel, varscan2
- GOLGB1 | c.4501del p.S1501Vfs*38 | Frame Shift Del (DEL) | VAF 33/194 reads (17%) | called by mutect2, pindel, varscan2
- GPR158 | c.1587G>A p.M529I | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.173); called by muse, mutect2
- GPRC6A | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GRIK4 | c.368del p.P123Qfs*15 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- GSAP | c.1856del p.L619* | Frame Shift Del (DEL) | VAF 13/69 reads (19%) | called by mutect2, pindel, varscan2
- HECTD2 | c.1144dup p.I382Nfs*22 | Frame Shift Ins (INS) | VAF 34/202 reads (17%) | called by mutect2, varscan2
- HPS3 | c.1477A>G p.T493A | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2
- IGHG3 | c.30dup p.L11Pfs*89 | Frame Shift Ins (INS) | VAF 17/69 reads (25%) | called by mutect2, pindel, varscan2
- IKZF5 | c.15del p.K5Nfs*8 | Frame Shift Del (DEL) | VAF 20/88 reads (23%) | called by mutect2, varscan2
- IL1RAPL1 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- IP6K1 | c.448_449del p.K150Efs*26 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | called by mutect2, pindel, varscan2
- ITGAL | c.2668del p.D890Tfs*9 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- ITPRIPL1 | c.887dup p.L296Ffs*5 (on ENST00000439118 / NM_001008949.3; = p.L304Ffs*5 on NM_178495.6) | Frame Shift Ins (INS) | VAF 26/93 reads (28%) | called by mutect2, pindel, varscan2
- KANSL1 | c.536del p.G179Efs*23 | Frame Shift Del (DEL) | VAF 11/84 reads (13%) | called by mutect2, pindel, varscan2
- KCNH8 | c.1758G>T p.Q586H | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.149); called by muse, mutect2
- KIAA1549L | c.5520del p.K1840Nfs*36 (on ENST00000321505; = p.K2137Nfs*36 on NM_012194.3) | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- KIF21A | c.2851C>A p.L951I (on ENST00000361418 / NM_001378440.1; = p.L938I on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.042); called by muse, mutect2
- KMT2E | c.2619del p.K873Nfs*8 | Frame Shift Del (DEL) | VAF 36/124 reads (29%) | called by mutect2, pindel, varscan2
- KNL1 | c.2603del p.K868Sfs*39 (on ENST00000346991 / NM_170589.5; = p.K842Sfs*39 on NM_144508.5) | Frame Shift Del (DEL) | VAF 52/210 reads (25%) | called by mutect2, pindel, varscan2
- LARGE1 | c.1152dup p.K385Qfs*24 | Frame Shift Ins (INS) | VAF 25/125 reads (20%) | called by mutect2, pindel, varscan2
- LTBP3 | c.1784dup p.D596* | Frame Shift Ins (INS) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- MAPRE2 | c.581dup p.S195Vfs*13 | Frame Shift Ins (INS) | VAF 16/100 reads (16%) | called by mutect2, pindel, varscan2
- MCM3AP | c.1473dup p.K492Efs*5 | Frame Shift Ins (INS) | VAF 41/161 reads (25%) | called by mutect2, pindel, varscan2
- MICAL1 | c.132del p.L45Cfs*121 | Frame Shift Del (DEL) | VAF 16/66 reads (24%) | called by mutect2, pindel, varscan2
- MPHOSPH10 | c.1111del p.I371Lfs*4 | Frame Shift Del (DEL) | VAF 27/113 reads (24%) | called by mutect2, pindel, varscan2
- MTG1 | c.986del p.P329Rfs*28 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel, varscan2
- NCOR1 | c.963del p.V322Wfs*4 | Frame Shift Del (DEL) | VAF 94/345 reads (27%) | called by mutect2, pindel, varscan2
- OPLAH | c.2362del p.H788Tfs*31 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, varscan2
- OR4K5 | c.639_640dup p.L214Sfs*34 | Frame Shift Ins (INS) | VAF 48/240 reads (20%) | called by mutect2, varscan2
- OR52E8 | c.771del p.F257Lfs*9 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | called by mutect2, pindel, varscan2
- PAK6 | c.113del p.P38Hfs*30 | Frame Shift Del (DEL) | VAF 21/75 reads (28%) | called by mutect2, pindel, varscan2
- PBX1 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2
- PCED1A | c.1229A>T p.Y410F | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.025); called by muse, mutect2
- PHLDA1 | c.509dup p.C171Vfs*246 | Frame Shift Ins (INS) | VAF 8/44 reads (18%) | called by mutect2, pindel, varscan2
- PIWIL1 | c.2334dup p.I779Yfs*10 | Frame Shift Ins (INS) | VAF 24/108 reads (22%) | called by mutect2, pindel, varscan2
- PROM1 | c.2482T>C p.Y828H | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PSD | c.785del p.P262Hfs*32 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | called by mutect2, pindel, varscan2
- PSME4 | c.984del p.K328Nfs*3 | Frame Shift Del (DEL) | VAF 21/106 reads (20%) | called by mutect2, pindel, varscan2
- PTBP2 | c.1377del p.P460Lfs*15 (on ENST00000426398 / NM_001300986.2; = p.P452Lfs*15 on NM_021190.4) | Frame Shift Del (DEL) | VAF 35/149 reads (23%) | called by mutect2, pindel, varscan2
- PXDN | c.1403dup p.G470Rfs*19 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel, varscan2
- QSER1 | c.4750del p.I1584* (on ENST00000399302; = p.I1713* on NM_001076786.3) | Frame Shift Del (DEL) | VAF 16/71 reads (23%) | called by mutect2, pindel, varscan2
- RARS2 | c.1055del p.K352Sfs*10 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | called by mutect2, pindel, varscan2
- RGS12 | c.335del p.G112Dfs*9 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- RIC8B | c.958del p.T320Qfs*8 | Frame Shift Del (DEL) | VAF 16/141 reads (11%) | called by mutect2, pindel, varscan2
- RLF | c.5222del p.N1741Ifs*21 | Frame Shift Del (DEL) | VAF 27/170 reads (16%) | called by mutect2, pindel, varscan2
- RNF32 | c.160del p.R54Efs*6 | Frame Shift Del (DEL) | VAF 35/146 reads (24%) | called by mutect2, pindel, varscan2
- RPS6KB2 | c.1273del p.L425Sfs*69 | Frame Shift Del (DEL) | VAF 13/116 reads (11%) | called by mutect2, pindel, varscan2
- SGPP1 | c.1068del p.I357Lfs*3 | Frame Shift Del (DEL) | VAF 19/101 reads (19%) | called by mutect2, pindel, varscan2
- SH3BP2 | c.1024dup p.R342Pfs*7 | Frame Shift Ins (INS) | VAF 17/90 reads (19%) | called by mutect2, pindel, varscan2
- SLAMF8 | c.427T>C p.S143P | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SLC24A4 | c.764del p.F255Sfs*40 | Frame Shift Del (DEL) | VAF 17/79 reads (22%) | called by mutect2, pindel, varscan2
- SPPL2B | c.383del p.G128Vfs*32 | Frame Shift Del (DEL) | VAF 19/69 reads (28%) | called by mutect2, pindel, varscan2
- SRGAP3 | c.2548del p.V850* | Frame Shift Del (DEL) | VAF 17/65 reads (26%) | called by mutect2, pindel, varscan2
- STAB1 | c.4520del p.G1507Afs*84 | Frame Shift Del (DEL) | VAF 13/56 reads (23%) | called by mutect2, pindel, varscan2
- STXBP1 | c.1780A>G p.S594G | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.827); called by muse, mutect2
- SUPT20H | c.1838del p.N613Ifs*8 (on ENST00000350612 / NM_001014286.3; = p.N614Ifs*8 on NM_017569.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 36/184 reads (20%) | called by mutect2, varscan2
- TEX10 | c.1580del p.F527Sfs*10 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- TGIF1 | c.80_81del p.V27Afs*9 (on ENST00000330513 / NM_001374396.1; = p.V47Afs*9 on NM_003244.4) | Frame Shift Del (DEL) | VAF 35/84 reads (42%) | called by pindel, varscan2
- TKTL2 | c.1541T>C p.V514A | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- TMTC2 | c.1369del p.Y457Mfs*6 | Frame Shift Del (DEL) | VAF 38/157 reads (24%) | called by mutect2, pindel, varscan2
- TNFRSF6B | c.464del p.P155Qfs*101 | Frame Shift Del (DEL) | VAF 14/77 reads (18%) | called by mutect2, pindel, varscan2
- TNKS2 | c.577del p.M193* | Frame Shift Del (DEL) | VAF 50/185 reads (27%) | called by mutect2, pindel, varscan2
- TSPYL2 | c.378del p.S127Afs*20 | Frame Shift Del (DEL) | VAF 50/96 reads (52%) | called by mutect2, pindel, varscan2
- UBASH3A | c.214del p.Q72Rfs*40 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- UBQLN2 | c.1574del p.P525Lfs*71 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- VPS54 | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2
- ZBTB5 | c.277del p.E93Rfs*4 | Frame Shift Del (DEL) | VAF 23/81 reads (28%) | called by mutect2, pindel, varscan2
- ZBTB7C | c.960del p.P321Lfs*18 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, varscan2
- ZFP14 | c.148dup p.S50Ffs*2 | Frame Shift Ins (INS) | VAF 16/83 reads (19%) | called by mutect2, pindel, varscan2
- ZNF101 | c.1075del p.T359Lfs*28 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | called by mutect2, pindel, varscan2
- ZNF131 | c.433del p.R145Gfs*26 | Frame Shift Del (DEL) | VAF 15/177 reads (8%) | called by mutect2, pindel
- ZNF331 | c.182del p.N61Tfs*5 | Frame Shift Del (DEL) | VAF 16/134 reads (12%) | called by mutect2, pindel, varscan2
- ABCA7 | c.4071C>T p.P1357= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs758371487, COSV54031245; called by muse, mutect2
- ABCA8 | c.618A>G p.G206= | Silent (SNP) | VAF 46/169 reads (27%) | catalogued as COSV52203285; called by muse, mutect2, varscan2
- ACD | c.547C>T p.L183= (on ENST00000620338; = p.L94= on NM_022914.3) | Silent (SNP) | VAF 25/95 reads (26%) | catalogued as COSV54668222; called by muse, mutect2, varscan2
- ADAMTS2 | c.1593G>A p.G531= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV51071904, COSV51082417; called by muse, mutect2, varscan2
- ADAMTSL4 | c.621C>T p.N207= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as rs587708719, COSV54998640; called by muse, mutect2, varscan2
- ADCY9 | c.2622G>A p.S874= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as rs1436665952, COSV53576565; called by muse, mutect2, varscan2
- ALDH1L1 | c.411G>A p.A137= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs759539289, COSV56415037; called by muse, mutect2, varscan2
- ANAPC10 | c.267T>C p.Y89= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV58739777; called by muse, mutect2, varscan2
- ANKS6 | c.825C>T p.D275= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as COSV62050690; called by muse, mutect2, varscan2
- AQP12B | c.213C>T p.H71= (on ENST00000621682; = p.H83= on NM_001102467.2) | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as rs373980987; called by muse, mutect2, varscan2
- ARFGEF1 | c.4491G>A p.A1497= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as rs769048042, COSV51609917, COSV51610083; called by muse, mutect2, varscan2
- BRD1 | c.456C>T p.N152= | Silent (SNP) | VAF 42/161 reads (26%) | catalogued as rs142139061; called by muse, mutect2, varscan2
- BRD7 | c.549A>G p.E183= | Silent (SNP) | VAF 45/181 reads (25%) | catalogued as COSV101164881; called by muse, mutect2, varscan2
- BRD8 | c.2442G>A p.T814= (on ENST00000254900 / NM_139199.2; = p.T887= on NM_006696.4) | Silent (SNP) | VAF 39/121 reads (32%) | catalogued as rs760824840, COSV50151562; called by muse, mutect2, varscan2
- C1QL1 | c.516C>T p.G172= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV53647340; called by muse, mutect2, varscan2
- C4BPA | c.459T>C p.R153= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV65536617; called by muse, mutect2, varscan2
- CA8 | c.300G>A p.S100= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs749173414, COSV100526643, COSV58772456; called by muse, mutect2, varscan2
- CAMK2A | c.868C>T p.L290= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV62246659; called by muse, mutect2, varscan2
- CARMIL2 | c.3339A>G p.P1113= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99537621; called by mutect2, varscan2
- CASC3 | c.1011C>T p.G337= | Silent (SNP) | VAF 24/146 reads (16%) | catalogued as COSV52867258, COSV52867445; called by muse, mutect2, varscan2
- CBLB | c.2058T>C p.C686= | Silent (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- CCDC74A | c.168C>T p.S56= | Silent (SNP) | VAF 49/247 reads (20%) | catalogued as COSV54607191; called by muse, mutect2, varscan2
- CDH16 | c.1650G>A p.T550= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs749336595, COSV55337130; called by muse, mutect2, varscan2
- CELSR2 | c.7542C>A p.S2514= | Silent (SNP) | VAF 34/107 reads (32%) | catalogued as COSV99603713; called by muse, mutect2, varscan2
- CES3 | c.1245C>T p.D415= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as rs751744410, COSV57593914; called by muse, mutect2, varscan2
- CFH | c.774G>A p.P258= | Silent (SNP) | VAF 36/148 reads (24%) | catalogued as rs146074007; called by muse, mutect2, varscan2
- CHD2 | c.72C>A p.A24= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100560675; called by muse, mutect2
- CHRND | c.360C>T p.D120= | Silent (SNP) | VAF 56/214 reads (26%) | catalogued as rs764641517, COSV51320829; called by muse, mutect2, varscan2
- CIC | c.705C>T p.G235= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV50588441; called by muse, mutect2, varscan2
- CIITA | c.2103C>T p.A701= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs564280588, COSV60858306; called by muse, mutect2, varscan2
- COMMD2 | c.72C>T p.V24= | Silent (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- CORO7 | c.669C>A p.T223= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV52030889; called by muse, mutect2, varscan2
- CPNE4 | c.81G>A p.E27= | Silent (SNP) | VAF 27/184 reads (15%) | catalogued as COSV101456671; called by muse, mutect2, varscan2
- CPXCR1 | c.507T>C p.N169= | Silent (SNP) | VAF 36/70 reads (51%) | catalogued as COSV52162727; called by muse, mutect2, varscan2
- CROCC | c.504G>A p.R168= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV65012611; called by muse, mutect2
- CTBP2 | c.330C>T p.N110= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs1297386295, COSV58334816, COSV58337298; called by muse, mutect2, varscan2
- CYTH3 | c.1050C>T p.R350= (on ENST00000396741; = p.R349= on NM_004227.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 54/187 reads (29%) | catalogued as rs761402109, COSV60361046; called by muse, mutect2, varscan2
- CYTH3 | c.639C>A p.P213= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV63439252; called by muse, mutect2, varscan2
- DARS2 | c.384A>G p.G128= | Silent (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- DCAF5 | c.1962A>G p.E654= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as COSV100432418; called by muse, mutect2
- DENND4C | c.1023T>C p.H341= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as COSV66822345; called by muse, mutect2, varscan2
- DGKI | c.1614T>C p.H538= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV99934008; called by muse, mutect2, varscan2
- DHRS2 | c.186C>T p.H62= | Silent (SNP) | VAF 36/153 reads (24%) | catalogued as rs747248253, COSV51633985; called by muse, mutect2, varscan2
- DMKN | c.309C>A p.A103= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV60086904; called by muse, mutect2, varscan2
- DMXL1 | c.159T>G p.A53= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV60713568; called by muse, mutect2, varscan2
- DNM3 | c.1500G>A p.Q500= | Silent (SNP) | VAF 97/327 reads (30%) | catalogued as COSV62459735; called by muse, mutect2, varscan2
- ECE1 | c.435C>A p.R145= | Silent (SNP) | VAF 76/306 reads (25%) | catalogued as COSV99941768; called by muse, mutect2, varscan2
- EHBP1L1 | c.2025A>G p.V675= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV58573541; called by muse, mutect2, varscan2
- EXTL1 | c.666C>T p.P222= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs754732049, COSV65337730; called by muse, mutect2, varscan2
- FAM110B | c.654T>C p.S218= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs1265110829, COSV64065787; called by muse, mutect2, varscan2
- FAM78A | c.267C>T p.G89= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as COSV64844758; called by muse, mutect2, varscan2
- FAM83C | c.1437G>A p.L479= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV65583356; called by muse, mutect2, varscan2
- FANK1 | c.840G>A p.T280= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as rs777836625, COSV64128850; called by muse, mutect2, varscan2
- FBN3 | c.7650C>T p.R2550= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV54463269; called by muse, mutect2
- FSCN3 | c.507C>T p.D169= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as rs371544770; called by muse, mutect2, varscan2
- GALNT13 | c.1251C>T p.I417= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV67223815; called by muse, mutect2, varscan2
- GHR | c.168C>T p.C56= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as CM910178, COSV50115324; called by muse, mutect2, varscan2
- GJA4 | c.339G>A p.L113= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs1329277479, COSV60725488; called by muse, mutect2, varscan2
- GLI3 | c.3393G>A p.A1131= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV67886652, COSV67889536; called by muse, mutect2, varscan2
- GLIS3 | c.219C>T p.N73= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as rs764619575, COSV67944687; called by muse, mutect2, varscan2
- GUCA1B | c.561C>T p.S187= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV50003486; called by muse, mutect2, varscan2
- HECTD4 | c.9696C>T p.G3232= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs1333967512, COSV66393462; called by muse, varscan2
- HLA-DMB | c.25C>T p.L9= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV66870816; called by muse, mutect2
- HLA-DRA | c.60T>C p.A20= | Silent (SNP) | VAF 27/108 reads (25%) | catalogued as COSV100895068; called by muse, mutect2, varscan2
- HMX2 | c.336G>A p.S112= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs896410936, COSV100378861, COSV60592917; called by muse, mutect2, varscan2
- HNRNPU | c.1095G>A p.P365= (on ENST00000283179; = p.P427= on NM_004501.3) | Silent (SNP) | VAF 68/260 reads (26%) | catalogued as rs752673312, COSV51691675; called by muse, varscan2
- HOMER1 | c.393C>T p.S131= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs745316039, COSV56526880; called by muse, mutect2, varscan2
- HPS6 | c.672C>T p.G224= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV54625849; called by muse, mutect2, varscan2
- HSPG2 | c.6771C>T p.A2257= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as rs149569423; called by muse, mutect2, varscan2
- IGF2 | c.330G>A p.R110= (on ENST00000434045 / NM_001127598.3; = p.R54= on NM_000612.6) | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV56099557; called by muse, mutect2, varscan2
- IMPG2 | c.1794C>T p.D598= | Silent (SNP) | VAF 37/133 reads (28%) | catalogued as rs371805004; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- KRT14 | c.312T>C p.F104= | Silent (SNP) | VAF 71/316 reads (22%) | catalogued as rs371274993; called by muse, mutect2, varscan2
- KSR2 | c.384C>T p.C128= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as rs371982174; called by muse, mutect2, varscan2
- LAMTOR3 | c.249T>C p.F83= | Silent (SNP) | VAF 81/289 reads (28%) | catalogued as COSV56952330; called by muse, mutect2, varscan2
- LGR5 | c.1836G>A p.V612= | Silent (SNP) | VAF 112/389 reads (29%) | catalogued as COSV57005767; called by muse, mutect2, varscan2
- LPO | c.2040A>G p.P680= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV51859740; called by muse, mutect2
- LRR1 | c.1056T>C p.D352= | Silent (SNP) | VAF 13/156 reads (8%) | catalogued as COSV53563887; called by muse, mutect2
- LTA4H | c.942C>T p.H314= | Silent (SNP) | VAF 37/158 reads (23%) | catalogued as COSV57382855; called by muse, mutect2, varscan2
- MAGI1 | c.1248G>A p.Q416= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as COSV58330514; called by muse, mutect2, varscan2
- MAP3K6 | c.1293C>T p.C431= | Silent (SNP) | VAF 39/152 reads (26%) | catalogued as rs775463638, COSV62888682, COSV62888787; called by muse, mutect2, varscan2
- MBD6 | c.2862G>A p.R954= | Silent (SNP) | VAF 36/133 reads (27%) | catalogued as COSV63074962; called by muse, mutect2, varscan2
- MED27 | c.156T>C p.F52= | Silent (SNP) | VAF 7/107 reads (7%) | catalogued as rs982451649, COSV52597074; called by muse, mutect2
- MINK1 | c.2730T>C p.P910= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99544852; called by mutect2, varscan2
- MRGPRX1 | c.363C>T p.C121= | Silent (SNP) | VAF 14/218 reads (6%) | catalogued as COSV100245966; called by muse, mutect2
- MRPL13 | c.334C>T p.L112= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV60367840; called by muse, mutect2, varscan2
- NAT10 | c.231G>A p.Q77= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as rs930475418; called by muse, mutect2
- NEDD4 | c.69C>T p.S23= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as rs916306729, COSV59062760; called by muse, mutect2, varscan2
- NETO1 | c.399A>G p.L133= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as rs371964955; called by muse, mutect2, varscan2
- NLGN2 | c.1071C>T p.G357= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as rs762728787, COSV57210513; called by muse, mutect2, varscan2
- NSL1 | c.606C>T p.S202= | Silent (SNP) | VAF 47/172 reads (27%) | catalogued as COSV65329273; called by muse, mutect2, varscan2
- OAT | c.1188A>G p.R396= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV64347784; called by muse, mutect2
- OR2M5 | c.567C>T p.C189= | Silent (SNP) | VAF 67/367 reads (18%) | catalogued as COSV63546424; called by muse, mutect2, varscan2
- OTOF | c.4194C>T p.P1398= (on ENST00000272371 / NM_194248.3; = p.P631= on NM_004802.4) | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs749026372, COSV55505690; called by muse, mutect2, varscan2
- OTOGL | c.1398G>A p.V466= (on ENST00000547103; = p.V457= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV72006755; called by muse, mutect2, varscan2
- PAPPA | c.3330T>C p.Y1110= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV60285158; called by muse, mutect2, varscan2
- PAPPA2 | c.1812C>T p.L604= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs1234995660, COSV62779706; called by muse, varscan2
- PCDHGA10 | c.2226G>A p.S742= | Silent (SNP) | VAF 10/113 reads (9%) | catalogued as rs1408496357, COSV53964267; called by muse, mutect2
- PCDHGB7 | c.1842C>T p.P614= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs1268060859, COSV53964278; called by muse, mutect2, varscan2
- PCTP | c.108C>A p.T36= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV52122837; called by muse, mutect2, varscan2
- PDZRN3 | c.1866C>T p.N622= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs553747931, COSV55190281; called by muse, mutect2, varscan2
- PHF10 | c.372A>G p.R124= | Silent (SNP) | VAF 14/220 reads (6%) | catalogued as COSV59322457; called by muse, mutect2
- PLA2G2F | c.324C>T p.H108= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs200119328, COSV64280071; called by muse, mutect2, varscan2
- PLXND1 | c.4425C>T p.A1475= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as rs189832202, COSV60714695; called by muse, mutect2, varscan2
- PNMA2 | c.384C>T p.G128= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs755196239, COSV72908542; called by muse, mutect2, varscan2
- PPP4C | c.882G>T p.R294= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as COSV54222145; called by muse, mutect2, varscan2
- PPP4R2 | c.51G>A p.G17= | Silent (SNP) | VAF 38/156 reads (24%) | catalogued as COSV55594566, COSV55596878; called by muse, mutect2, varscan2
- PPRC1 | c.4812G>A p.L1604= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs1428843073, COSV53386083; called by muse, mutect2, varscan2
- PRR7 | c.489G>A p.P163= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV52790096; called by muse, mutect2
- PSEN2 | c.771C>T p.G257= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as rs7539017, COSV60916600; called by muse, mutect2, varscan2
- PTGS1 | c.1650C>T p.G550= | Silent (SNP) | VAF 45/153 reads (29%) | catalogued as rs201417140; called by muse, mutect2, varscan2
- QDPR | c.483C>T p.C161= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV55550340; called by muse, mutect2, varscan2
- RASA1 | c.1392T>C p.R464= | Silent (SNP) | VAF 18/301 reads (6%) | catalogued as COSV99169777; called by muse, mutect2
- RBPJL | c.1314C>T p.D438= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV59213964; called by muse, mutect2, varscan2
- RC3H1 | c.2235C>T p.P745= | Silent (SNP) | VAF 32/113 reads (28%) | catalogued as COSV51202552; called by muse, mutect2, varscan2
- REEP6 | c.417C>T p.V139= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1411517185, COSV52013700; called by muse, mutect2, varscan2
- RFX2 | c.690G>A p.E230= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as COSV57942174; called by muse, mutect2, varscan2
- RHCG | c.564C>T p.G188= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs772093651, COSV51514536; called by muse, mutect2, varscan2
- RMND5B | c.411C>T p.A137= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs111290494; called by muse, mutect2, varscan2
73 further variants in this file (0 protein-altering or splice-affecting, 57 silent, 16 other) are not listed here.
